Somatic mutation profile of tumor specimen TCGA-A3-3374-01A (aliquot TCGA-A3-3374-01A-01D-0966-08) from TCGA case TCGA-A3-3374, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.7 years (18,890 days).
Specimen TCGA-A3-3374-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4b06424-2c7e-4421-a10b-e07c9308cfd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3374-11A (Solid Tissue Normal), aliquot TCGA-A3-3374-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2397162c-b116-4a2a-8e3f-a28c9bb9b4a1

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPA5 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 83/358 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV62568721; called by muse, mutect2, varscan2
- EHHADH | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51627625; called by muse, mutect2
- GRIA1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as rs750421563, COSV53588586; called by muse, varscan2
- LILRA1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as rs759678804, COSV52177807; called by muse, mutect2, varscan2
- MTCL1 | c.4904C>A p.T1635K (on ENST00000306329 / NM_001378206.1; = p.T1316K on NM_015210.4) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV60403076; called by muse, mutect2, varscan2
- NAV1 | c.3535C>A p.Q1179K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55213969; called by muse, mutect2, varscan2
- OCA2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.693); catalogued as rs749410903, COSV62338286; called by muse, mutect2
- SLC25A21 | c.331-1G>C p.X111_splice | Splice Site (SNP) | VAF 12/148 reads (8%) | catalogued as COSV58714481; called by muse, mutect2
- SUSD5 | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58875647; called by muse, mutect2, varscan2
- TRMT12 | c.444C>G p.F148L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV60776513; called by muse, mutect2
- MYO19 | c.1804C>A p.L602M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13C | c.3399dup p.V1134Cfs*5 (on ENST00000644861 / NM_020821.3; = p.V1091Cfs*5 on NM_017684.5) | Frame Shift Ins (INS) | VAF 25/171 reads (15%) | called by mutect2, pindel, varscan2
- AMER3 | c.1281C>T p.H427= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs532564436, COSV58465088; called by muse, mutect2, varscan2
- ANGPT1 | c.1314A>G p.K438= | Silent (SNP) | VAF 40/159 reads (25%) | catalogued as rs1169426289, COSV52430426; called by muse, mutect2, varscan2
- BLK | c.759C>A p.G253= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV52049387; called by muse, mutect2, varscan2
- CAPN2 | c.1752A>C p.L584= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV54333970, COSV54338368; called by muse, mutect2, varscan2
- SETX | c.6483A>G p.L2161= | Silent (SNP) | VAF 61/279 reads (22%) | catalogued as COSV56378718; called by muse, mutect2, varscan2
- SORCS3 | c.2625C>T p.I875= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs775261134, COSV100863404, COSV63793264, COSV63794690; called by muse, mutect2, varscan2
